Gene-level copy-number profile of tumor specimen TCGA-VR-A8Q7-01A from TCGA case TCGA-VR-A8Q7, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 60.6 years (22,149 days).
Specimen TCGA-VR-A8Q7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.441930b3-1f9b-44b7-ae00-591f58dffced.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8Q7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/326b5774-fa79-4b0f-87ec-abe9317906b6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 790; copy number 2: 7,687; copy number 3: 18,140; copy number 4: 20,196; copy number 5: 6,927; copy number 6: 2,981; copy number 7: 525; copy number 8: 785; copy number 9: 786; copy number 10: 58; copy number 11: 80; copy number 12: 326; copy number 13: 372; copy number 15: 123; copy number 16: 27; copy number 18: 4; copy number 21: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-A8Q7-01A-11D-A37B-01): tumor purity 0.36, ploidy 3.91, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,787 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,113,679–109,397,918, 6 genes, copy number 9 (within-gene range 4–9): ELAPOR1, SARS1, CELSR2, PSRC1, MYBPHL, SORT1.
- chr1:224,896,262–226,333,655, 32 genes, copy number 11: DNAH14, LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703, AL512343.1, ACBD3, ACBD3-AS1, AL592045.1, MIXL1, LIN9, YBX1P9, AL359742.1.
- chr1:234,550,542–235,161,283, 25 genes, copy number 11–16: AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34.
- chr1:235,190,034–235,190,116, 1 gene, copy number 16: MIR4753.
- chr3:189,956,728–192,917,856, 34 genes, copy number 9 (within-gene range 7–9): P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2.
- chr5:58,198–45,895,970, 710 genes, copy number 11–15 (broad region; genes not listed).
- chr6:34,685,355–34,888,071, 10 genes, copy number 9: RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA, RNY3P15, TAF11.
- chr6:111,555,381–111,606,906, 2 genes, copy number 9 (within-gene range 4–9): TRAF3IP2, Z97989.1.
- chr6:122,643,388–122,809,720, 5 genes, copy number 9: AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A.
- chr7:5,419,827–22,357,154, 230 genes, copy number 9–16 (broad region; genes not listed).
- chr7:38,239,580–64,037,958, 473 genes, copy number 9 (broad region; genes not listed).
- chr8:119,730,774–120,373,573, 10 genes, copy number 9 (within-gene range 5–9): TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr8:127,072,694–127,227,541, 1 gene, copy number 12 (within-gene range 6–15): CASC19.
- chr8:127,253,213–127,742,951, 9 genes, copy number 12: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,890,720, 2 genes, copy number 12: MIR1204, AC084123.1.
- chr12:30,628,988–31,369,301, 24 genes, copy number 13: IPO8, AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6.
- chr12:69,212,108–69,959,097, 22 genes, copy number 15–21: AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr12:69,946,543–69,947,081, 1 gene, copy number 15: AC078922.1.
- chr12:71,582,293–71,927,248, 13 genes, copy number 10: AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:123,973,215–124,316,024, 2 genes, copy number 10 (within-gene range 5–10): AC068790.8, RFLNA.
- chr12:124,085,761–124,882,668, 18 genes, copy number 10–18: AC068790.9, AC026358.1, NCOR2, MIR6880, AC073916.1, AC073592.1, AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6, AC073592.8, AC073592.2, AC073592.10, AC073592.4, AC073593.1, SCARB1, AC073593.2.
- chr16:67,517,862–69,085,182, 86 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr17:4,433,940–4,823,434, 28 genes, copy number 10: SPNS3, AC127521.1, AC118754.1, SPNS2, MYBBP1A, GGT6, AC118754.2, TXNP4, SMTNL2, LINC01996, RNU6-955P, ALOX15, PELP1, AC091153.2, AC091153.3, AC091153.1, ARRB2, MED11, AC091153.4, CXCL16, ZMYND15, TM4SF5, VMO1, AC233723.2, GLTPD2, PSMB6, AC233723.1, PLD2.
- chr17:59,784,813–59,785,035, 1 gene, copy number 10: AC040904.1.
- chr18:2,506,628–3,478,978, 37 genes, copy number 9: AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,656,282, 5 genes, copy number 9: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
